Somatic mutation profile of tumor specimen 0DLHP2 from CCDI case PBBZFM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,773 days).
Specimen 0DLHP2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aae7ba14-45c7-4ad6-9432-af09e1c3e08b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c6ff9d3-d377-49e7-8a4f-458cd79c2066

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Intron 1, Silent 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA4 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 29/1088 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1255071797, COSV66005087, COSV66006082; called by muse, mutect2
- GPAT3 | c.1126-7A>T | Splice Region (SNP) | VAF 10/226 reads (4%) | catalogued as rs1270631135; called by muse, mutect2
- DEDD | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 61/268 reads (23%) | called by muse, mutect2, varscan2
- OR8B12 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 38/725 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ABCA4 | c.4557G>A p.T1519= | Silent (SNP) | VAF 45/944 reads (5%) | catalogued as rs371535991; called by muse, mutect2
- KIF1B | c.2115+7118_2115+7123dup | Intron (INS) | VAF 86/344 reads (25%) | called by mutect2, varscan2
- TMEM240 | c.-88C>A | 5'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
